Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A70D, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A70D-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology	Final Results
Surgical Pathology	Final

CASE NUMBER:
DIAGNOSIS:

1. Tumor, aortocaval peripancreatic, excision: Paraganglioma
Lymph nodes: no tumor seen (0/3)
2. Tumor, presacral, excision: Paraganglioma
3. Lymph node, right presacral common iliac, excision: Lymph nodes, no tumor seen (0/7)

NOTE:

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the Laboratory of Pathology. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: female with SDHB+ mutation, h/o cardiac and retroperitoneal paragangliomas s/p exploratory laparotomy, excision of aortocaval and pelvic retroperitoneal paraganglioma, retroperitoneal lymphadenectomy Specimen Taken For Protocol: 01 - Yes Allocate Order to Protocol:

PROCEDURE: Pre-Operative Diagnosis: retroperitoneal paraganglioma
Post-Operative
Diagnosis: same Operative Findings: ureter preserved, well-circumscribed paragangliomas

lymph nodes with
hypervascular, reddish discoloration

SPECIMENS SUBMITTED: 1. TUMOR, Aorta caval peri pancreatic
2. TUMOR, Pre sacral
3. LYMPH NODES, Right pericaval common iliac

GROSS DESCRIPTION: Received at Surgical Pathology are 3 freshly submitted specimens, each labeled with the patient's name, medical record number, date of birth and further designated as:

1. "Aortocaval peripancreatic tumor with adjacent lymph nodes 2.5" is

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By:

Do not file in Medical Record

[page 2 of 2]
an ovoid tan-pink tumor nodule 2.3 cm in greatest dimensions with attached fibroadipose tissue, containing a possible lymph node (1 cm in greatest dimensions), overall the specimen measuring 3.5 x 2.5 x 1.3 cm. The external surface is inked in black. The tumor nodule is bisected revealing a soft red-tan cut surface. Gross photographs are taken. Approximately 60% of tissue from the nodule and 0.4 x 0.4 x 0.2 cm of fibroadipose tissue is procured for

Approximately 0.3 cm of the tumor nodule is procured for . The remainder of the specimen is placed into formalin and submitted Pathology for permanent processing. The procurement was performed by Received at

Surgical Pathology container is labeled with the patient's name, medical record number, date of birth and further designated as "aortocaval peripancreatic tumor". The specimen consists of two soft tissue fragments, in aggregate measures 2.0 x 2.0 x 2.0 cm. Cut surface reveals a yellow-tan heterogeneous cut surface. The specimen is serially sectioned and submitted entirely in 3 white cassettes labeled as

2. "Presacral tumor for research and perm" is a globoid tan-pink soft nodule measuring 3.0 x 2.5 x 2.0 cm. The external surface is inked in black. It is bisected revealing a soft red-brown cut surface. Photographs are taken. Approximately 60% of tissue of the nodule is procured for The remainder of the specimen is placed into formalin and submitted to for permanent processing. The procurement was performed by and Received at is a specimen that consists of soft tissue fragment measuring 2.5 x 2 x 1.0 cm. The cut surface reveals hemorrhagic, maroon-colored, heterogeneous cut surface. The specimen is serially sectioned and submitted entirely in 3 white cassettes labeled as

3. "Right presacral common iliac". The specimen consists of a yellow-tan fibroadipose tissue measuring 4.0 x 3.0 x 1.0 cm. Two candidate lymph nodes are appreciated and submitted entirely in white cassette labeled as The remainder of the specimen is serially sectioned and entirely submitted in :

Gross Description dictated by

No consultants
Accessioned:
Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

Concurrent Primary Tumor		✓

7/24/13

perman

7/24/13

7/24/13

Source: NCI Genomic Data Commons file 02233485-5edc-4359-a82c-f43adc3e82e0 (TCGA-QR-A70D.AA5BFB7A-0449-4C53-BC29-B7C52616F4F3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).